FM case AD10586 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/490bdc72-f2c1-481a-a1b0-ed7ef6bc3790

Male, 58.9 years: diagnosis not reported by GDC; metastasis biopsied or resected from the thorax. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Metastatic.
